Somatic mutation profile of tumor specimen TCGA-CM-4750-01A (aliquot TCGA-CM-4750-01A-01D-1408-10) from TCGA case TCGA-CM-4750, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 34.2 years (12,478 days).
Specimen TCGA-CM-4750-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 502e48be-b56a-42d5-b0d1-cd44d67e0934.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-4750-10A (Blood Derived Normal), aliquot TCGA-CM-4750-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4662da18-e9f0-493d-bbce-2fe831fcb765

The open-access MAF lists 95 somatic variants for this specimen: 67 protein-altering or splice-affecting, 23 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 23, Nonsense Mutation 6, Splice Site 3, RNA 3, Frame Shift Del 2, Intron 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 46/178 reads (26%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2, varscan2
- TP53 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 51/73 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1057519999, COSV52661127, COSV52664176, COSV52966384; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.1604C>T p.T535I (on ENST00000506720 / NM_001322402.2; = p.T467I on NM_015236.6) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV101547031, COSV101547234; called by muse, mutect2
- ANO3 | c.1418T>A p.V473D | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99846385; called by muse, mutect2, varscan2
- ASB3 | c.1004A>G p.N335S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.079); catalogued as COSV55078816; called by muse, mutect2, varscan2
- ATP10A | c.2917G>A p.V973M | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs763937984, COSV63521614; called by muse, mutect2, varscan2
- ATP2B2 | c.2021C>T p.P674L (on ENST00000352432; = p.P640L on NM_001683.5) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs746292256, COSV59504852; called by muse, mutect2, varscan2
- BRAF | c.505-1G>A p.X169_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as COSV56317156; called by muse, mutect2, varscan2
- C1orf112 | c.749del p.R250Lfs*53 | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | catalogued as rs775767262, COSV53681714; called by mutect2, pindel, varscan2
- CDAN1 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as COSV62332216; called by muse, mutect2, varscan2
- CDH10 | c.2151G>T p.R717S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751881000, COSV52568276, COSV52586111; called by muse, mutect2, varscan2
- CDHR2 | c.3548G>A p.R1183Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs751180171, COSV56143372, COSV99991046; called by muse, mutect2, varscan2
- CFAP47 | c.5067G>A p.M1689I | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs200011963, COSV57974247, COSV57975930; called by muse, mutect2, varscan2
- CSMD3 | c.6730C>A p.Q2244K (on ENST00000297405 / NM_001363185.1; = p.Q2140K on NM_052900.3) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV52276602, COSV99827125; called by muse, mutect2, varscan2
- CTPS2 | c.1364C>A p.T455N | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63723744; called by muse, mutect2
- DDX10 | c.2432A>C p.D811A | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV59438459; called by muse, mutect2, varscan2
- DEPDC5 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99835122; called by muse, mutect2, varscan2
- DOT1L | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs370589055; called by muse, mutect2, varscan2
- EYS | c.191C>G p.T64S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV100676305; called by muse, mutect2, varscan2
- F2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs371085757; called by muse, mutect2, varscan2
- F8 | c.3812G>A p.R1271K | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100811459; called by muse, mutect2
- FAM184A | c.2617C>A p.Q873K | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); catalogued as COSV100137689; called by muse, mutect2, varscan2
- FAM184A | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58857377; called by muse, mutect2, varscan2
- HIVEP2 | c.3352G>A p.G1118R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs751162519, COSV50012523, COSV50039198; called by muse, mutect2, varscan2
- IL25 | c.446A>C p.K149T | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100198017; called by muse, mutect2
- JARID2 | c.3053A>T p.K1018I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV59195507; called by muse, mutect2, varscan2
- KCNB1 | c.2485G>T p.E829* | Nonsense Mutation (SNP) | VAF 147/237 reads (62%) | catalogued as COSV65568996, COSV65570260; called by muse, mutect2, varscan2
- KIF1A | c.4705C>T p.R1569C (on ENST00000320389 / NM_001379639.1; = p.R1561C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs372226807, COSV57495312; called by muse, mutect2, varscan2
- KIF26B | c.5788C>T p.R1930W | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1349034241, COSV63648548; called by muse, mutect2, varscan2
- KMT2C | c.7163G>A p.R2388H | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100072263, COSV51483454; called by muse, mutect2, varscan2
- KNTC1 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as COSV100338749, COSV61083006; called by muse, mutect2, varscan2
- LRRC7 | c.2380G>T p.D794Y (on ENST00000651989 / NM_001370785.2; = p.D761Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV50560149; called by muse, mutect2, varscan2
- LTBP4 | c.3575C>A p.A1192E (on ENST00000308370 / NM_001042544.1; = p.A1155E on NM_003573.2) | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.932); catalogued as COSV52588312; called by muse, mutect2, varscan2
- MAGEC1 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as COSV99595504; called by muse, mutect2
- MCHR2 | c.587+2T>G p.X196_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as COSV56003771; called by muse, mutect2, varscan2
- MMP26 | c.535T>A p.S179T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV56173556; called by muse, mutect2, varscan2
- MYH14 | c.2797C>T p.R933C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs757682381, COSV51827840; called by muse, mutect2, varscan2
- MYH2 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs569489518, COSV55431886, COSV55435762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.4802C>T p.P1601L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs758702351, COSV62758325; called by muse, mutect2, varscan2
- NLRP6 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as COSV56461500; called by muse, mutect2, varscan2
- NOS1 | c.2524G>T p.E842* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV57614736, COSV57618887; called by muse, mutect2, varscan2
- PDYN | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370283678, COSV54101461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGAM4 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV100430661; called by muse, mutect2, varscan2
- PITPNM1 | c.3592G>A p.V1198M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); catalogued as rs781622887, COSV54161566; called by muse, mutect2, varscan2
- PPM1L | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); catalogued as rs757453078, COSV55565447; called by muse, mutect2, varscan2
- PROX2 | c.1638C>A p.S546R (on ENST00000556489 / NM_001243007.1; = p.S319R on NM_001080408.2) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV71520140; called by muse, mutect2, varscan2
- RAB3C | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 37/120 reads (31%) | catalogued as COSV51435808; called by muse, mutect2, varscan2
- RAF1 | c.987A>C p.K329N | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV52582351; called by muse, mutect2
- RALGPS1 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV52229488; called by muse, mutect2, varscan2
- SCRIB | c.3346C>T p.R1116C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782034055, COSV57591788; called by muse, mutect2
- SIAH3 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs771136468, COSV68552712; called by muse, mutect2, varscan2
- STAMBP | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV59898101; called by muse, mutect2, varscan2
- THBS4 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as rs145442755; called by muse, mutect2, varscan2
- TIMD4 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs774551130, COSV50858482; called by muse, mutect2, varscan2
- TJP3 | c.2440_2463del p.G814_G821del | In Frame Del (DEL) | VAF 17/43 reads (40%) | catalogued as rs1449589367; called by mutect2, varscan2
- TRPC7 | c.1951G>A p.V651I | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs372192731; called by muse, mutect2, varscan2
- UBE3B | c.2654A>G p.H885R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV61076777; called by muse, mutect2, varscan2
- UGGT2 | c.1278A>T p.L426F | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs779238022, COSV65078018; called by muse, mutect2, varscan2
- UNC5B | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs543519250, COSV58979974; called by muse, mutect2, varscan2
- VPS33B | c.476A>G p.E159G | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV60981260; called by muse, mutect2, varscan2
- WNT10B | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs149890665, COSV56404789; called by muse, mutect2, varscan2
- ZNF236 | c.2581C>T p.H861Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV53494679; called by muse, mutect2, varscan2
- ZNF804A | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs765819874, COSV56437566; called by muse, mutect2, varscan2
- CUL1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); called by muse, mutect2
- FBXW7 | c.109_115del p.V37Rfs*24 | Frame Shift Del (DEL) | VAF 84/185 reads (45%) | called by mutect2, pindel, varscan2
- LBR | c.164_165+1del p.X55_splice | Splice Site (DEL) | VAF 13/105 reads (12%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 130/258 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK2 | c.10119C>T p.D3373= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs374986732; called by muse, mutect2, varscan2
- APBB1 | c.51C>T p.H17= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs769578645, COSV54975062; called by muse, mutect2, varscan2
- C1QTNF2 | c.519C>A p.P173= (on ENST00000393975; = p.P128= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV67433166; called by muse, mutect2, varscan2
- C9 | c.1344C>T p.T448= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as rs1366887364, COSV54677385, COSV99661865; called by muse, mutect2, varscan2
- CHERP | c.1209C>T p.A403= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs746988306, COSV52226990; called by muse, mutect2, varscan2
- CHRNA4 | c.1728C>T p.D576= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs1218265056, COSV64720799; called by muse, mutect2, varscan2
- CLDN18 | c.420C>A p.A140= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as COSV51737605; called by muse, mutect2, varscan2
- CSTF3 | c.654T>G p.R218= | Silent (SNP) | VAF 59/162 reads (36%) | catalogued as COSV60613583; called by muse, mutect2, varscan2
- CUX2 | c.2184G>A p.P728= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1418665919, COSV55643452; called by muse, mutect2, varscan2
- FBXW9 | c.129C>T p.S43= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV63509604; called by muse, mutect2
- FIGNL2 | c.147C>T p.D49= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV73729285; called by muse, mutect2, varscan2
- GRM7 | c.414C>T p.N138= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs909354514, COSV63128922; called by muse, mutect2, varscan2
- KIDINS220 | c.1365C>T p.T455= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1315682621, COSV56757587, COSV99876255; called by muse, mutect2, varscan2
- LILRB5 | c.621G>A p.S207= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs144716655, COSV100300498; called by muse, mutect2
- MCFD2 | c.141C>T p.H47= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs778325740, COSV60178316; called by muse, mutect2, varscan2
- MCPH1 | c.2157G>A p.L719= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs1371885876, COSV57339526; called by muse, mutect2, varscan2
- PCDHA12 | c.1788G>A p.A596= | Silent (SNP) | VAF 65/270 reads (24%) | catalogued as rs1329010026, COSV56534386; called by muse, mutect2, varscan2
- PIK3R4 | c.2766G>A p.P922= | Silent (SNP) | VAF 61/96 reads (64%) | catalogued as rs543155374, COSV63243153; called by muse, mutect2, varscan2
- RNF216 | c.660G>A p.P220= (on ENST00000425013 / NM_207116.3; = p.P277= on NM_207111.4) | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs762487101, COSV66292127; called by muse, mutect2, varscan2
- S1PR2 | c.573G>A p.V191= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100495305; called by muse, mutect2
- TNFSF11 | c.402C>T p.I134= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV53479067; called by muse, mutect2, varscan2
- TTN | c.23163C>T p.N7721= (on ENST00000591111; = p.N6794= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs199576800, COSV60025026; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- UNC79 | c.4419G>A p.T1473= (on ENST00000393151 / NM_001346218.2; = p.T1296= on NM_020818.5) | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as rs755525028, COSV56379629; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446676 C>A | 3'Flank (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- MIR1283-2 | n.28C>T | RNA (SNP) | VAF 14/70 reads (20%) | catalogued as rs971367084; called by muse, mutect2, varscan2
- RPL26P30 | n.924C>T | RNA (SNP) | VAF 94/169 reads (56%) | catalogued as rs549312796; called by muse, mutect2, varscan2
- TTN | c.10361-5544G>T | Intron (SNP) | VAF 26/69 reads (38%) | catalogued as COSV60257049; called by muse, mutect2, varscan2
- ZNF271P | n.1189A>C | RNA (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
